Somatic mutation profile of tumor specimen TARGET-30-PARUPT-01A (aliquot TARGET-30-PARUPT-01A-01D) from TARGET case TARGET-30-PARUPT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.7 years (994 days).
Specimen TARGET-30-PARUPT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00a6a65e-c0db-47d6-8c8b-f6260e238ba7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARUPT-10A (Blood Derived Normal), aliquot TARGET-30-PARUPT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26ff8e72-227f-457b-b355-5f4d5f3d6c21

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PASK | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs747065146, COSV52158897; called by muse, mutect2, varscan2
- FCGBP | c.8943G>A p.K2981= | Silent (SNP) | VAF 44/375 reads (12%) | catalogued as rs530808402; called by muse, mutect2, varscan2
